Somatic mutation profile of cancer-model specimen HCM-CSHL-0429-C06-85C (3D Organoid, passage 6; aliquot HCM-CSHL-0429-C06-85C-01D-A88G-36), derived from the primary tumor of HCMI case HCM-CSHL-0429-C06, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX.
Specimen HCM-CSHL-0429-C06-85C: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95ea4df6-8d33-477d-9c01-884e90594134.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0429-C06-11A (Solid Tissue Normal), aliquot HCM-CSHL-0429-C06-11A-11D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16f4ef4a-b7f9-4943-91dc-8250317bc330

The open-access MAF lists 96 somatic variants for this specimen: 73 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 20, Nonsense Mutation 14, Frame Shift Del 6, Frame Shift Ins 2, Intron 2, Translation Start Site 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP7B | c.3305T>C p.I1102T | Missense Mutation (SNP) | VAF 238/479 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs560952220, CM950119; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 101/222 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 413/413 reads (100%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANK1 | c.4504C>T p.R1502C | Missense Mutation (SNP) | VAF 199/454 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs745317361; called by muse, mutect2, varscan2
- ARAP3 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 302/674 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs1279389642; called by muse, mutect2, varscan2
- BCLAF1 | c.838G>T p.G280* | Nonsense Mutation (SNP) | VAF 39/183 reads (21%) | catalogued as COSV62144908; called by muse, varscan2
- BFSP2 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 196/833 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs200874347, COSV56588428; called by muse, mutect2, varscan2
- CASP8 | c.344C>G p.S115* (on ENST00000432109 / NM_033355.3; = p.S147* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 206/206 reads (100%) | catalogued as COSV51847755, COSV51852205; called by muse, mutect2, varscan2
- CFAP91 | c.2272G>C p.E758Q | Missense Mutation (SNP) | VAF 118/252 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.087); catalogued as COSV56340367; called by muse, mutect2, varscan2
- CYLC2 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 141/264 reads (53%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.859); catalogued as rs375836898, COSV66335963; called by muse, mutect2, varscan2
- DENND2B | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 235/490 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142799946, COSV58201975; called by muse, varscan2
- ENPP1 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 82/134 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs746849474; called by muse, mutect2, varscan2
- ENPP7 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 22/576 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs376245774, COSV60387696; called by muse, mutect2
- EPS8 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 168/369 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as rs773063073, COSV55530839; called by muse, mutect2, varscan2
- FAT1 | c.3784C>T p.R1262* | Nonsense Mutation (SNP) | VAF 108/365 reads (30%) | catalogued as rs369805914; called by muse, mutect2, varscan2
- H4-16 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 219/460 reads (48%) | catalogued as COSV100797595; called by muse, varscan2
- HLA-A | c.627dup p.K210Qfs*11 | Frame Shift Ins (INS) | VAF 32/38 reads (84%) | catalogued as rs199474609; called by mutect2, varscan2
- IGSF21 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 222/457 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774817306, COSV52125830; called by muse, mutect2, varscan2
- IL13 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 211/445 reads (47%) | catalogued as COSV100449390; called by muse, mutect2, varscan2
- KCNT1 | c.1889C>T p.S630L (on ENST00000488444; = p.S649L on NM_020822.3) | Missense Mutation (SNP) | VAF 86/970 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs747671066, COSV53704769; ClinVar: likely benign; called by muse, mutect2
- KIAA1217 | c.1073G>C p.R358T | Missense Mutation (SNP) | VAF 221/468 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1357921393; called by muse, mutect2, varscan2
- LAMA3 | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 190/400 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs763063287; called by muse, varscan2
- MED17 | c.871T>C p.W291R | Missense Mutation (SNP) | VAF 121/265 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1352488616; called by muse, mutect2, varscan2
- MIB2 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 318/638 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1406677488, COSV61757598; called by muse, varscan2
- MIIP | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 191/386 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779477951, COSV52426933; called by muse, mutect2, varscan2
- NOTCH1 | c.1591G>T p.E531* | Nonsense Mutation (SNP) | VAF 405/732 reads (55%) | catalogued as COSV53073732, COSV53076022; called by muse, mutect2
- NOTCH1 | c.1255+1G>T p.X419_splice | Splice Site (SNP) | VAF 214/536 reads (40%) | catalogued as COSV53064284; called by muse, varscan2
- ONECUT3 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 390/390 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1444968801, COSV66639474; called by muse, mutect2, varscan2
- OR12D2 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 245/245 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747616224, COSV101011264; called by muse, mutect2, varscan2
- OR4C16 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as rs376991618, COSV58942597; called by muse, mutect2, varscan2
- OR6C6 | c.935G>C p.R312T | Missense Mutation (SNP) | VAF 66/112 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV64455637, COSV64455785; called by muse, varscan2
- PCDHAC1 | c.2314C>G p.R772G | Missense Mutation (SNP) | VAF 187/358 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV53836704; called by muse, mutect2, varscan2
- PRDM9 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 139/288 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99690562; called by muse, mutect2, varscan2
- PTGES2 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 273/477 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753136190; called by muse, mutect2, varscan2
- PTPN14 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 108/177 reads (61%) | catalogued as COSV65290050; called by muse, mutect2, varscan2
- RASA1 | c.1285G>T p.E429* | Nonsense Mutation (SNP) | VAF 88/88 reads (100%) | catalogued as COSV57191263; called by muse, mutect2, varscan2
- SCAF8 | c.2852G>T p.G951V | Missense Mutation (SNP) | VAF 77/274 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); catalogued as rs1438874200; called by muse, mutect2, varscan2
- SETD2 | c.1618C>T p.R540* | Nonsense Mutation (SNP) | VAF 139/258 reads (54%) | catalogued as rs201756643, COSV57434166; called by muse, mutect2, varscan2
- SLC17A8 | c.553G>A p.V185I | Missense Mutation (SNP) | VAF 79/140 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as rs778461278, COSV60122539; called by muse, varscan2
- TMPRSS6 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 204/518 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs376470679; called by muse, mutect2
- TRIM77 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 119/269 reads (44%) | SIFT tolerated (1); PolyPhen possibly damaging (0.482); catalogued as rs1181369147; called by muse, mutect2, varscan2
- TTC21A | c.3557G>A p.R1186H | Missense Mutation (SNP) | VAF 251/484 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs199697874, COSV56190221; called by muse, mutect2, varscan2
- ANK3 | c.9388G>A p.G3130R | Missense Mutation (SNP) | VAF 131/312 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC158 | c.1961A>G p.E654G | Missense Mutation (SNP) | VAF 223/382 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLDN22 | c.315G>C p.L105F | Missense Mutation (SNP) | VAF 116/327 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CNNM4 | c.1439del p.N480Tfs*20 | Frame Shift Del (DEL) | VAF 86/351 reads (25%) | called by mutect2, pindel, varscan2
- CYP2S1 | c.1206C>A p.D402E | Missense Mutation (SNP) | VAF 197/382 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- FASTKD1 | c.2178C>A p.Y726* | Nonsense Mutation (SNP) | VAF 47/275 reads (17%) | called by muse, mutect2, varscan2
- FKBP4 | c.814A>G p.I272V | Missense Mutation (SNP) | VAF 111/231 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRE | c.1386T>A p.D462E | Missense Mutation (SNP) | VAF 394/394 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- GPR88 | c.501_523del p.L168Afs*212 | Frame Shift Del (DEL) | VAF 260/674 reads (39%) | called by mutect2, pindel, varscan2
- H2BC21 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 45/142 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, varscan2
- KCNMA1 | c.3614C>G p.S1205C (on ENST00000286628 / NM_001161352.2; = p.S1147C on NM_002247.4) | Missense Mutation (SNP) | VAF 110/425 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KHNYN | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 102/342 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); called by muse, varscan2
- LRCH1 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 130/270 reads (48%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- MDGA2 | c.2139G>T p.W713C (on ENST00000399232 / NM_001113498.2; = p.W415C on NM_182830.4) | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- MME | c.594dup p.V199Sfs*4 | Frame Shift Ins (INS) | VAF 84/199 reads (42%) | called by mutect2, pindel, varscan2
- MTHFD1 | c.458del p.L153Wfs*24 | Frame Shift Del (DEL) | VAF 70/213 reads (33%) | called by mutect2, pindel, varscan2
- NCF2 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 96/326 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NCKAP5L | c.3149A>G p.Y1050C | Missense Mutation (SNP) | VAF 260/627 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- PCDH12 | c.3357G>A p.M1119I | Missense Mutation (SNP) | VAF 346/673 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- PCDHB4 | c.914_936delinsTTGGAT p.K305Ifs*9 | Frame Shift Del (DEL) | VAF 30/185 reads (16%) | called by pindel, varscan2*
- PDHX | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 99/198 reads (50%) | called by muse, mutect2, varscan2
- PRUNE2 | c.8617G>T p.E2873* | Nonsense Mutation (SNP) | VAF 150/426 reads (35%) | called by muse, mutect2, varscan2
- RANBP17 | c.243G>T p.Q81H | Missense Mutation (SNP) | VAF 72/297 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- SGCZ | c.821C>G p.S274* | Nonsense Mutation (SNP) | VAF 126/309 reads (41%) | called by muse, mutect2, varscan2
- SHPRH | c.2243A>T p.Y748F | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SPATA31D1 | c.226T>A p.F76I | Missense Mutation (SNP) | VAF 103/254 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SPATA5L1 | c.664T>C p.Y222H | Missense Mutation (SNP) | VAF 381/742 reads (51%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENT5D | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 195/195 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- TSEN15 | c.508A>C p.N170H (on ENST00000361641 / NM_001300764.2; = p.N166H on NM_052965.4) | Missense Mutation (SNP) | VAF 90/134 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- VCAN | c.7641_7648del p.D2548Gfs*15 | Frame Shift Del (DEL) | VAF 54/158 reads (34%) | called by mutect2, pindel, varscan2
- ZNF638 | c.740_747del p.N247Sfs*11 | Frame Shift Del (DEL) | VAF 106/174 reads (61%) | called by mutect2, pindel, varscan2
- ABCC11 | c.1995C>T p.D665= | Silent (SNP) | VAF 246/485 reads (51%) | catalogued as rs150571618; called by muse, mutect2, varscan2
- APBB2 | c.825G>A p.P275= | Silent (SNP) | VAF 149/273 reads (55%) | catalogued as rs1325619270, COSV55963923; called by muse, mutect2, varscan2
- CDR2 | c.1161G>A p.K387= | Silent (SNP) | VAF 271/559 reads (48%) | called by muse, mutect2, varscan2
- CPXM2 | c.549G>A p.A183= | Silent (SNP) | VAF 133/322 reads (41%) | catalogued as rs199715698, COSV53865032; called by muse, mutect2, varscan2
- HDGFL1 | c.357G>A p.P119= | Silent (SNP) | VAF 337/338 reads (100%) | catalogued as rs1206449947; called by muse, varscan2
- IGLV4-3 | c.243C>T p.I81= | Silent (SNP) | VAF 195/397 reads (49%) | catalogued as rs759503573; called by muse, mutect2, varscan2
- LAMA3 | c.225G>A p.R75= | Silent (SNP) | VAF 347/757 reads (46%) | catalogued as rs989382762; called by muse, mutect2, varscan2
- MED17 | c.1095G>A p.E365= | Silent (SNP) | VAF 128/300 reads (43%) | catalogued as COSV52600501; called by muse, mutect2
- MTNR1A | c.276G>A p.G92= | Silent (SNP) | VAF 138/255 reads (54%) | called by muse, mutect2, varscan2
- NKX2-2 | c.744C>T p.N248= | Silent (SNP) | VAF 308/611 reads (50%) | catalogued as rs760495343, COSV65819649; called by muse, mutect2, varscan2
- NUDT3 | c.285C>G p.V95= | Silent (SNP) | VAF 6/187 reads (3%) | catalogued as COSV101657170; called by muse, mutect2
- PFKFB2 | c.882A>T p.I294= | Silent (SNP) | VAF 85/246 reads (35%) | called by muse, mutect2, varscan2
- POU4F1 | c.111G>A p.L37= | Silent (SNP) | VAF 244/460 reads (53%) | called by muse, mutect2, varscan2
- PPP1R13L | c.1902G>A p.A634= | Silent (SNP) | VAF 354/902 reads (39%) | called by muse, mutect2, varscan2
- SLC44A1 | c.423C>T p.S141= | Silent (SNP) | VAF 145/262 reads (55%) | called by muse, mutect2, varscan2
- SLC8A3 | c.2190C>T p.Y730= (on ENST00000381269 / NM_183002.3; = p.Y728= on NM_033262.4) | Silent (SNP) | VAF 228/354 reads (64%) | catalogued as rs149109491, COSV53687621; ClinVar: likely benign; called by muse, varscan2
- STMN4 | c.93G>A p.S31= | Silent (SNP) | VAF 153/324 reads (47%) | catalogued as COSV56109921; called by muse, mutect2, varscan2
- TSNARE1 | c.861A>G p.T287= | Silent (SNP) | VAF 254/519 reads (49%) | called by muse, mutect2, varscan2
- ZBTB18 | c.276G>A p.L92= | Silent (SNP) | VAF 161/255 reads (63%) | catalogued as COSV62398285; called by muse, mutect2, varscan2
- ZNF236 | c.2112C>T p.I704= | Silent (SNP) | VAF 186/414 reads (45%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-4464dup | Intron (INS) | VAF 60/167 reads (36%) | called by mutect2, pindel, varscan2
- UNC13B | c.1168-14826_1168-14814del | Intron (DEL) | VAF 125/367 reads (34%) | called by mutect2, pindel, varscan2
- UVSSA | c.*8640G>A | 3'UTR (SNP) | VAF 342/1018 reads (34%) | called by muse, varscan2
